Gene-level copy-number profile of tumor specimen TCGA-L5-A8NL-01A from TCGA case TCGA-L5-A8NL, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 56.2 years (20,542 days).
Specimen TCGA-L5-A8NL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.856ed591-30cf-430d-a0fb-35dba3ddfa09.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NL-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91ac5b70-66f7-4013-8b8a-ae2afb546895

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 949; copy number 2: 15,538; copy number 3: 13,349; copy number 4: 25,488; copy number 5: 2,613; copy number 6: 726; copy number 7: 170; copy number 8: 347; copy number 9: 135; copy number 11: 20; copy number 12: 139; copy number 13: 30; copy number 17: 98; copy number 22: 18; copy number 23: 113; copy number 34: 11; copy number 37: 8; copy number 45: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NL-01A-12D-A37B-01): tumor purity 0.42, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr18:5,954,706–6,415,237, 1 gene (within-gene range 0–2): L3MBTL4.
- chr18:6,256,747–6,601,836, 9 genes: L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P.
- chr18:14,179,097–14,252,140, 1 gene (within-gene range 0–2): ANKRD20A5P.
- chr18:14,222,008–15,330,282, 42 genes: RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 573 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,599,541–37,034,515, 35 genes, copy number 9 (within-gene range 4–9): PSMB2, C1orf216, CLSPN, AL354864.1, AGO4, AGO1, CFAP97P1, AL139286.2, AL139286.1, AGO3, AL138787.2, AL138787.1, TEKT2, ADPRS, COL8A2, TRAPPC3, MAP7D1, RN7SL131P, THRAP3, UBE2V2P4, SH3D21, EVA1B, AL591845.1, STK40, LSM10, RNU4-27P, OSCP1, SNORA63C, MRPS15, CSF3R, FTLP18, AL596257.1, AC117945.2, AC117945.1, GRIK3.
- chr6:51,975,673–53,631,400, 57 genes, copy number 9: RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3, PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564.
- chr13:32,303,699–35,673,022, 42 genes, copy number 11–13 (within-gene range 3–13): ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13.
- chr17:39,603,536–39,747,291, 11 genes, copy number 34: NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:58,166,982–61,485,110, 122 genes, copy number 23–45 (broad region; genes not listed).
- chr17:62,136,972–64,662,307, 98 genes, copy number 17 (broad region; genes not listed).
- chr18:47,390–1,408,344, 43 genes, copy number 9: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr18:20,946,906–28,177,946, 137 genes, copy number 12–22 (within-gene range 12–24) (broad region; genes not listed).
- chr18:28,651,732–28,653,208, 1 gene, copy number 12: ARIH2P1.
- chr18:44,039,471–44,071,701, 2 genes, copy number 13: AC083760.1, RNA5SP455.
- chr18:63,476,958–64,677,993, 19 genes, copy number 12: SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1.
- chr18:65,423,958–66,069,647, 6 genes, copy number 13: LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1.

Autosomal genes at a single copy (total copy number 1): 949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
